FM case AD15763 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung.
https://portal.gdc.cancer.gov/cases/5b62784a-de24-49fc-8cd0-59cf9739bd89

Female, 68.1 years: Adenocarcinoma, NOS (ICD-O-3 8140/3) of the lung; metastasis biopsied or resected from the lymph node. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Metastatic.
